Gene-level copy-number profile of tumor specimen TCGA-59-2372-01A from TCGA case TCGA-59-2372, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2.
Specimen TCGA-59-2372-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f20b8655-d80d-4b0a-9df6-c8e1e534a710.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-59-2372-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/16a34c80-d4b7-4ecd-997c-6d5ba775939d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,279; copy number 2: 18,340; copy number 3: 20,460; copy number 4: 10,511; copy number 5: 7,685; copy number 6: 892; copy number 7: 156; copy number 8: 209; copy number 9: 245; copy number 10: 8; copy number 11: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-59-2372-01A-01D-1043-01): tumor purity 0.97, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:91,485,793–91,486,870, 1 gene: AL356118.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 649 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,640,157–40,423,326, 177 genes, copy number 8–10 (within-gene range 5–10) (broad region; genes not listed).
- chr1:44,405,194–46,413,848, 73 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:82,212,413–84,690,803, 31 genes, copy number 11 (within-gene range 3–11): AL157944.1, LINC01362, LINC01361, AC116099.1, LINC01712, LINC01725, AL035706.1, TTLL7, TTLL7-IT1, AC104454.1, AC104454.2, AL359504.1, PRKACB, TXN2P1, NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP.
- chr3:165,772,904–186,772,986, 367 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr3:186,930,325–187,078,553, 1 gene, copy number 8 (within-gene range 2–8): ST6GAL1.

Autosomal genes at a single copy (total copy number 1): 547. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
